CCDI case PBBXMP — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Spinal cord, cranial nerves, and other parts of central nervous system.
https://portal.gdc.cancer.gov/cases/f23028c4-6819-49c1-bd22-88fb9c5f3b5f

Demographics
Sex at birth: female; Vital status: Alive.

Diagnoses (1)
1. Myxopapillary ependymoma: ICD-O-3 morphology code: 9394/1; Tissue or organ of origin: Spinal cord; Age at diagnosis: 14.5 years (5,310 days).

Biospecimens (3 samples)
- Sample 0DMBLE: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DMBLY: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DMBM6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
